Somatic mutation profile of tumor specimen SM-JU33S (aliquot 7316UP-1302) from CPTAC case C524103, project CPTAC-3 (Other and unspecified urinary organs — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Urethra.
Specimen SM-JU33S: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22f76a5b-6579-42f6-a535-ed6373d157f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105274 (Blood Derived Normal), aliquot 7316UP-1302-1105274; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f50cd303-602d-4c78-8d0b-4abf0131aab8

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 15, Intron 2, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 141/257 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; called by muse, mutect2, varscan2
- ALOX5 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs778418203; called by muse, mutect2, varscan2
- CYP8B1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs961639006, COSV100296170; called by muse, mutect2, varscan2
- DOCK6 | c.2397C>A p.N799K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV52948752; called by muse, mutect2, varscan2
- DSCAM | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 121/351 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1227425619, COSV68021037; called by muse, mutect2, varscan2
- FRAS1 | c.811C>A p.H271N | Missense Mutation (SNP) | VAF 142/299 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.158); catalogued as COSV53598598; called by muse, mutect2, varscan2
- GPT2 | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs143451663; called by muse, mutect2, varscan2
- GRIN2B | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 216/445 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs761084398; called by muse, mutect2, varscan2
- LLGL1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs775418941, COSV57496026; called by muse, mutect2, varscan2
- MGAT5 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs768197190, COSV56094792; called by muse, mutect2, varscan2
- NBAS | c.1141dup p.I381Nfs*4 | Frame Shift Ins (INS) | VAF 58/244 reads (24%) | catalogued as rs772472509; called by mutect2, varscan2
- NEK10 | c.1718C>G p.S573C | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1264897408; called by muse, mutect2
- OR6Y1 | c.775A>G p.M259V | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs909829305; called by muse, mutect2, varscan2
- RASA2 | c.2275_2276del p.E759Kfs*12 | Frame Shift Del (DEL) | VAF 35/101 reads (35%) | catalogued as rs756946687; called by mutect2, pindel, varscan2
- REG3G | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs779615598, COSV55449323, COSV55450779; called by muse, mutect2, varscan2
- ROBO3 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs373820994; called by muse, mutect2, varscan2
- SYT4 | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV54904546; called by muse, mutect2, varscan2
- ZNF718 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101210245; called by muse, varscan2
- ATRX | c.3271A>T p.K1091* | Nonsense Mutation (SNP) | VAF 104/236 reads (44%) | called by muse, mutect2, varscan2
- CACNA1I | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 61/394 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A1 | c.4865G>A p.C1622Y | Missense Mutation (SNP) | VAF 182/476 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGF | c.953G>A p.C318Y | Missense Mutation (SNP) | VAF 27/324 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2
- IGKV5-2 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- NEB | c.11696T>G p.I3899S | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ORC1 | c.1901A>G p.Y634C | Missense Mutation (SNP) | VAF 281/615 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGAP2 | c.483C>G p.C161W (on ENST00000463452 / NM_001346398.2; = p.C222W on NM_014489.4) | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPA1 | c.1660C>T p.H554Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- SCUBE1 | c.703C>A p.H235N | Missense Mutation (SNP) | VAF 105/365 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SLC23A3 | c.742A>T p.R248W (on ENST00000409878 / NM_001144889.2; = p.G237= on NM_144712.5) | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SPATA31D3 | c.290A>C p.K97T | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2
- TEPSIN | c.832T>A p.C278S | Missense Mutation (SNP) | VAF 98/200 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIOBP | c.5250G>A p.W1750* | Nonsense Mutation (SNP) | VAF 194/749 reads (26%) | called by muse, mutect2, varscan2
- TRPC7 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 99/179 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ZNF718 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.124); called by muse, varscan2
- ZNF718 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, varscan2
- ZNF91 | c.2231G>A p.C744Y | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AKAP3 | c.2557C>T p.L853= | Silent (SNP) | VAF 54/166 reads (33%) | catalogued as rs780846438; called by muse, mutect2
- AQR | c.852C>T p.Y284= | Silent (SNP) | VAF 80/194 reads (41%) | called by muse, mutect2, varscan2
- CEP250 | c.5244C>T p.L1748= | Silent (SNP) | VAF 71/305 reads (23%) | catalogued as rs1296536087; called by muse, mutect2, varscan2
- DACT2 | c.1542G>A p.P514= | Silent (SNP) | VAF 87/244 reads (36%) | catalogued as rs890309903; called by muse, mutect2, varscan2
- EFCAB14 | c.108T>G p.P36= | Silent (SNP) | VAF 102/292 reads (35%) | called by muse, mutect2, varscan2
- FAM170B | c.768G>A p.E256= | Silent (SNP) | VAF 65/134 reads (49%) | catalogued as rs1358578431; called by muse, mutect2, varscan2
- GCN1 | c.7848T>A p.I2616= | Silent (SNP) | VAF 108/340 reads (32%) | called by muse, mutect2, varscan2
- MAP4K2 | c.1764G>C p.L588= | Silent (SNP) | VAF 64/207 reads (31%) | called by muse, varscan2
- MYO15A | c.2352G>A p.P784= | Silent (SNP) | VAF 130/682 reads (19%) | catalogued as rs748006735; called by muse, mutect2, varscan2
- NBEAL2 | c.888C>G p.P296= | Silent (SNP) | VAF 100/308 reads (32%) | catalogued as rs375562306; called by muse, mutect2, varscan2
- OCSTAMP | c.981A>G p.A327= | Silent (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2, varscan2
- PDCD7 | c.480G>A p.P160= | Silent (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- XKR4 | c.1488C>T p.F496= | Silent (SNP) | VAF 68/443 reads (15%) | called by muse, mutect2, varscan2
- XKR4 | c.1782C>T p.V594= | Silent (SNP) | VAF 90/362 reads (25%) | called by muse, mutect2, varscan2
- ZBTB10 | c.1269C>T p.F423= | Silent (SNP) | VAF 90/412 reads (22%) | called by muse, mutect2, varscan2
- CABIN1 | c.4117+57dup | Intron (INS) | VAF 74/341 reads (22%) | catalogued as rs766082760; called by mutect2, varscan2
- SMARCC1 | c.1899+20T>C | Intron (SNP) | VAF 70/154 reads (45%) | catalogued as rs1029053019; called by muse, mutect2, varscan2
